Somatic mutation profile of tumor specimen TCGA-06-2558-01A (aliquot TCGA-06-2558-01A-01D-1494-08) from TCGA case TCGA-06-2558, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 75.3 years (27,511 days).
Specimen TCGA-06-2558-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4e6467f-c61e-4fb0-bf86-32a34ab3bab8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-2558-10A (Blood Derived Normal), aliquot TCGA-06-2558-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ecb7a505-fa82-41a8-ad31-2b30537152db

The open-access MAF lists 77 somatic variants for this specimen: 55 protein-altering or splice-affecting, 22 silent.
By variant classification: Missense Mutation 50, Silent 22, Nonsense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 80/122 reads (66%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.841G>C p.D281H | Missense Mutation (SNP) | VAF 36/55 reads (65%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen possibly damaging (0.719); catalogued as rs764146326, CD137626, CM076566, CM153816, COSV52671054, COSV52674651, COSV52678614; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.750A>T p.E250D | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.845); catalogued as COSV50957674; called by muse, mutect2, varscan2
- ABCC5 | c.3122G>A p.R1041H | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs376038853; called by muse, mutect2, varscan2
- ACSM2B | c.1676A>G p.Q559R | Missense Mutation (SNP) | VAF 91/565 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0.01); catalogued as COSV61656906; called by muse, mutect2, varscan2
- ACSM4 | c.1289G>C p.C430S | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as COSV68066840; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.724T>A p.F242I | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV58441385, COSV58441585; called by muse, mutect2
- AQP10 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 87/260 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.877); catalogued as rs775690026, COSV61474501; called by muse, mutect2, varscan2
- BRIX1 | c.703C>G p.R235G | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57759330, COSV57760667; called by muse, mutect2, varscan2
- CACNA2D1 | c.1478C>G p.S493C | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV62373564; called by muse, mutect2, varscan2
- CD101 | c.257C>T p.T86M | Missense Mutation (SNP) | VAF 66/163 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as rs529866838, COSV56716276; called by muse, mutect2, varscan2
- CD163 | c.3034C>T p.R1012C | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs752858863, COSV63129802; called by muse, mutect2, varscan2
- CDKN1A | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as COSV55187185; called by muse, mutect2, varscan2
- CHSY3 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs777729488, COSV59272015; called by muse, mutect2, varscan2
- CLASP2 | c.3361C>T p.R1121* (on ENST00000359576; = p.R1120* on NM_015097.3 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/194 reads (4%) | catalogued as rs1350668772, COSV56276781, COSV56290313; called by muse, mutect2
- CLDN25 | c.79A>G p.T27A | Missense Mutation (SNP) | VAF 22/239 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.394); catalogued as COSV71620412; called by muse, mutect2, varscan2
- CLNK | c.154A>G p.R52G | Missense Mutation (SNP) | VAF 145/359 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.534); catalogued as COSV57011224; called by muse, mutect2, varscan2
- CORIN | c.2485G>T p.G829C | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56686992; called by muse, mutect2
- DDX11 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1046226646, COSV52511760; called by muse, mutect2, varscan2
- DNAH17 | c.13346C>T p.A4449V | Missense Mutation (SNP) | VAF 151/339 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs143246806, COSV53143544; called by muse, mutect2, varscan2
- ENPEP | c.2000G>T p.R667I | Missense Mutation (SNP) | VAF 104/274 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV54447366; called by muse, mutect2, varscan2
- FADS3 | c.634G>C p.A212P | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.478); catalogued as COSV53877446; called by muse, mutect2, varscan2
- FAM234B | c.188A>G p.D63G | Missense Mutation (SNP) | VAF 65/161 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.742); catalogued as rs769080937, COSV52192731; called by muse, mutect2, varscan2
- FAM47B | c.1490A>T p.K497M | Missense Mutation (SNP) | VAF 77/202 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as COSV61452616; called by muse, mutect2, varscan2
- FAT3 | c.7627C>T p.R2543* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as COSV53079774; called by muse, mutect2, varscan2
- GSDMA | c.1312C>T p.L438F | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV52856544; called by muse, mutect2, varscan2
- H2AP | c.53A>T p.Q18L | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV61910785; called by muse, mutect2, varscan2
- HELZ2 | c.2078C>T p.A693V (on ENST00000467148 / NM_001037335.2; = p.A124V on NM_033405.3) | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1484975022, COSV64409105; called by muse, mutect2, varscan2
- HERC1 | c.9953G>A p.R3318Q | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.968); catalogued as rs1422143134, COSV101496840, COSV71246056; called by muse, mutect2, varscan2
- IL21R | c.15G>A p.W5* | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | catalogued as COSV61968685; called by muse, mutect2, varscan2
- KDM6B | c.3149C>T p.P1050L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV54678207; called by muse, mutect2, varscan2
- KLHL34 | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV65278670; called by muse, mutect2, varscan2
- MPO | c.1117G>A p.G373S | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs776994403, COSV56561566; called by muse, mutect2, varscan2
- MYO1B | c.2329A>G p.K777E | Missense Mutation (SNP) | VAF 60/197 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as COSV58427572; called by muse, mutect2, varscan2
- NAP1L2 | c.799A>T p.K267* | Nonsense Mutation (SNP) | VAF 43/148 reads (29%) | catalogued as COSV65172218; called by muse, mutect2, varscan2
- OR51G1 | c.556A>T p.I186F | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV58968544; called by muse, mutect2, varscan2
- PCDH11X | c.1457C>T p.T486M | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs62621113, COSV53445288, COSV53466454; called by muse, mutect2, varscan2
- PKHD1 | c.2546C>A p.T849N | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs759247308, COSV61862379; called by muse, mutect2, varscan2
- PPP4R2 | c.742C>T p.L248F | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55594239; called by muse, mutect2, varscan2
- RBMS3 | c.1186G>T p.V396F (on ENST00000383767 / NM_001003793.3; = p.V380F on NM_014483.3) | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.019); catalogued as COSV56133160; called by muse, mutect2, varscan2
- RGS22 | c.1774C>T p.R592W | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as rs766770784, COSV62657743; called by muse, mutect2, varscan2
- RILP | c.700C>A p.R234S | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV53957536; called by muse, mutect2, varscan2
- RNF144A | c.283A>G p.K95E | Missense Mutation (SNP) | VAF 15/239 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as rs1432601534, COSV57980529; called by muse, mutect2
- SAMSN1 | c.1085T>A p.M362K | Missense Mutation (SNP) | VAF 109/311 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as COSV53467036, COSV53467999; called by muse, mutect2, varscan2
- SDC2 | c.280C>G p.Q94E | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.171); catalogued as COSV56225978; called by muse, mutect2, varscan2
- SEMA3C | c.1802T>C p.I601T | Missense Mutation (SNP) | VAF 81/257 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as COSV54841858; called by muse, mutect2, varscan2
- SERPINA5 | c.457T>C p.Y153H | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61573599; called by muse, mutect2
- SOCS6 | c.166A>G p.I56V | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV67546002; called by muse, mutect2, varscan2
- SPATA31A1 | c.3986G>A p.G1329D | Missense Mutation (SNP) | VAF 117/335 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.437); catalogued as COSV66533977; called by muse, mutect2, varscan2
- SRPK1 | c.362C>G p.A121G | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV60411268; called by muse, mutect2, varscan2
- STAB1 | c.4126G>A p.G1376R | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771020403, COSV58732587; called by muse, mutect2, varscan2
- TCF4 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 43/62 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV61891143; called by muse, mutect2, varscan2
- TRAPPC12 | c.1955G>T p.R652I | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV60845407; called by muse, mutect2, varscan2
- TTC30B | c.1423T>A p.Y475N | Missense Mutation (SNP) | VAF 42/685 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV68809220; called by muse, mutect2
- WDR72 | c.1424C>T p.S475L | Missense Mutation (SNP) | VAF 115/177 reads (65%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.588); catalogued as rs201559909, COSV64742066; called by muse, mutect2, varscan2
- ARHGAP45 | c.2811G>A p.T937= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs1025670372, COSV53123391; called by muse, mutect2, varscan2
- BCOR | c.4194A>G p.R1398= (on ENST00000378444 / NM_001123385.2; = p.R1364= on NM_017745.6) | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV60700934; called by muse, mutect2
- CAMK1G | c.204G>A p.E68= | Silent (SNP) | VAF 40/402 reads (10%) | catalogued as COSV50520326; called by muse, mutect2
- CNTN5 | c.213G>T p.G71= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV54281161, COSV54284408, COSV54332334; called by muse, mutect2
- CSNK1A1 | c.138G>A p.K46= | Silent (SNP) | VAF 62/204 reads (30%) | catalogued as rs760677105, COSV55793033; called by muse, mutect2, varscan2
- CYP4B1 | c.171T>C p.H57= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as COSV54721477; called by muse, mutect2
- DENND6A | c.645T>C p.P215= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV60767696; called by muse, mutect2, varscan2
- DGKK | c.1794T>G p.P598= | Silent (SNP) | VAF 135/368 reads (37%) | catalogued as COSV65706530; called by muse, mutect2, varscan2
- DNAJC4 | c.594C>T p.N198= | Silent (SNP) | VAF 80/250 reads (32%) | catalogued as COSV54172314; called by muse, mutect2, varscan2
- DSP | c.1464C>T p.N488= | Silent (SNP) | VAF 44/152 reads (29%) | catalogued as rs768526275, COSV65791390; called by muse, mutect2, varscan2
- FAM83A | c.708C>T p.F236= | Silent (SNP) | VAF 46/110 reads (42%) | catalogued as rs1310137595, COSV52684261; called by muse, mutect2, varscan2
- FLT4 | c.1740C>T p.A580= | Silent (SNP) | VAF 14/135 reads (10%) | catalogued as rs773249416, COSV56128790; called by muse, mutect2, varscan2
- FSCB | c.1581T>A p.L527= | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as COSV61216678, COSV61218114; called by muse, mutect2
- GNAT3 | c.711C>T p.D237= | Silent (SNP) | VAF 72/283 reads (25%) | catalogued as rs766464364, COSV68067964; called by muse, mutect2, varscan2
- HCRTR2 | c.369A>G p.G123= | Silent (SNP) | VAF 20/523 reads (4%) | catalogued as COSV63793972; called by muse, mutect2
- OR13C8 | c.783G>A p.K261= | Silent (SNP) | VAF 15/189 reads (8%) | catalogued as COSV58610566, COSV58610833; called by muse, mutect2
- PCSK2 | c.1008C>T p.N336= | Silent (SNP) | VAF 47/138 reads (34%) | catalogued as rs762559214, COSV52727055; called by muse, mutect2, varscan2
- PIR | c.66G>A p.A22= | Silent (SNP) | VAF 157/442 reads (36%) | catalogued as rs370522973, COSV62916272; called by muse, mutect2, varscan2
- SYT16 | c.543C>T p.D181= | Silent (SNP) | VAF 110/310 reads (35%) | catalogued as rs779568303, COSV70855156; called by muse, mutect2, varscan2
- THADA | c.1068G>A p.L356= | Silent (SNP) | VAF 77/218 reads (35%) | catalogued as COSV57676671; called by muse, mutect2, varscan2
- TMEM255A | c.612C>T p.Y204= | Silent (SNP) | VAF 90/292 reads (31%) | catalogued as rs372830851, COSV59028174, COSV59029063; called by muse, mutect2, varscan2
- TRIP12 | c.183G>A p.G61= | Silent (SNP) | VAF 183/501 reads (37%) | catalogued as COSV52259685; called by muse, mutect2, varscan2
